Somatic mutation profile of tumor specimen 0DRKKQ from CCDI case PBCGRA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,655 days).
Specimen 0DRKKQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01e0390b-d093-4619-9840-1d702f518c09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRKKX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30772291-829a-48a3-8343-bf6fad9de758

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSBG1 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 60/482 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs750963555, COSV51908982; called by muse, mutect2, varscan2
- DEFA5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.054); catalogued as rs765645949, COSV104399390; called by muse, mutect2, varscan2
- NOS3 | c.164dup p.S56Efs*27 | Frame Shift Ins (INS) | VAF 15/97 reads (15%) | catalogued as rs1323072201; called by mutect2, varscan2
- RRM2 | c.995T>C p.M332T | Missense Mutation (SNP) | VAF 146/440 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs778700518; called by muse, mutect2, varscan2
- CHIA | c.1322C>T p.A441V (on ENST00000343320; = p.A333V on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- HDAC7 | c.429C>A p.D143E (on ENST00000427332; = p.D182E on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/392 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HOXB1 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2
- IRX5 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MFSD6 | c.2246C>A p.P749Q | Missense Mutation (SNP) | VAF 239/500 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRRAP | c.11278G>A p.A3760T (on ENST00000359863 / NM_001244580.1; = p.A3731T on NM_003496.3) | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- GIMAP1 | c.771C>T p.G257= | Silent (SNP) | VAF 105/228 reads (46%) | catalogued as rs762097392, COSV100212090; called by muse, mutect2, varscan2
- GLS | c.861T>C p.C287= | Silent (SNP) | VAF 35/296 reads (12%) | called by muse, mutect2, varscan2
- MYOM3 | c.3231G>A p.S1077= | Silent (SNP) | VAF 45/431 reads (10%) | catalogued as rs774790768; called by muse, mutect2, varscan2
- NLRP8 | c.555C>T p.H185= | Silent (SNP) | VAF 45/411 reads (11%) | catalogued as rs112109260, COSV52589830; called by muse, mutect2, varscan2
- LMLN2 | c.-47C>T | 5'UTR (SNP) | VAF 48/91 reads (53%) | catalogued as rs547555959; called by muse, varscan2
